Somatic mutation profile of tumor specimen MP2PRT-PANWNY-TMP1-A (aliquot MP2PRT-PANWNY-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PANWNY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Blood; Age at diagnosis: 4.4 years (1,622 days).
Specimen MP2PRT-PANWNY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3e83fe2-06a3-4e2f-92f6-6daa2a39ab20.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANWNY-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANWNY-NM1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf033134-0f28-4869-95e2-86d2eedb2dc5

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 12, Silent 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 49/499 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- CKAP4 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 155/517 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as rs143926692; called by muse, mutect2, varscan2
- EGFR | c.2794C>T p.R932C | Missense Mutation (SNP) | VAF 28/499 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1223694747, COSV51783269, COSV51824002; called by muse, mutect2
- GALNT13 | c.682G>C p.D228H | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV67212482; called by muse, mutect2, varscan2
- MFAP3L | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 92/396 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1246565821, COSV64371761; called by muse, mutect2, varscan2
- MYH6 | c.2716C>T p.R906C | Missense Mutation (SNP) | VAF 37/286 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs143928061, COSV62448810; called by muse, mutect2, varscan2
- ADAM22 | c.2440A>T p.R814W | Missense Mutation (SNP) | VAF 87/327 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C7 | c.758T>C p.V253A | Missense Mutation (SNP) | VAF 78/261 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- MYLK | c.1784G>A p.S595N | Missense Mutation (SNP) | VAF 35/358 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NACC1 | c.934G>A p.V312I | Missense Mutation (SNP) | VAF 51/314 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SLC6A18 | c.1827G>A p.M609I | Missense Mutation (SNP) | VAF 113/820 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRDD3 | chr14:22449094 AAAGCTCTGTAGCACTGTGACTGGGGGATACGCA>TCT | Splice Site (DEL) | VAF 43/109 reads (39%) | called by pindel, varscan2*
- ZNF302 | c.370T>G p.S124A (on ENST00000627982; = p.S123A on NM_018675.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/236 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HUS1B | c.270G>A p.A90= | Silent (SNP) | VAF 143/614 reads (23%) | catalogued as rs1469406962, COSV100034286; called by muse, mutect2, varscan2
- LIPG | c.876T>C p.S292= | Silent (SNP) | VAF 53/414 reads (13%) | called by muse, mutect2, varscan2
- TAMALIN | c.816C>T p.G272= | Silent (SNP) | VAF 134/513 reads (26%) | called by muse, mutect2, varscan2
